Somatic mutation profile of tumor specimen 0DL6SF from CCDI case PBBZBS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Desmoplastic fibroma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 23.3 years (8,528 days).
Specimen 0DL6SF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe7e703f-09d4-4562-b5c8-6774e1ba0229.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dfe50eba-df2d-4a91-a7fd-2baa7df11e8d

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 136/493 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.40C>G p.Q14E | Missense Mutation (SNP) | VAF 36/762 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100252062; called by muse, mutect2
- ENAM | c.2607C>G p.S869R | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV68537079; called by muse, mutect2
- CNKSR2 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 18/435 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DIP2C | c.1939G>T p.V647F | Missense Mutation (SNP) | VAF 22/562 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2
- INF2 | c.1084G>T p.A362S | Missense Mutation (SNP) | VAF 16/564 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.348); called by muse, mutect2
- NUBPL | c.710A>G p.Q237R | Missense Mutation (SNP) | VAF 20/551 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PDGFRB | c.3025T>G p.Y1009D | Missense Mutation (SNP) | VAF 22/405 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.654); called by muse, mutect2
- SDAD1 | c.359A>G p.E120G | Missense Mutation (SNP) | VAF 36/822 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2
- ARMC4 | c.2727A>G p.A909= | Silent (SNP) | VAF 27/706 reads (4%) | called by muse, mutect2
- OR2W1 | c.231C>T p.I77= | Silent (SNP) | VAF 16/426 reads (4%) | called by muse, mutect2
- RBM12B | c.813A>G p.K271= | Silent (SNP) | VAF 14/424 reads (3%) | catalogued as rs1413327984, COSV66968446; called by muse, mutect2
- RHCE | c.21G>A p.R7= | Silent (SNP) | VAF 19/698 reads (3%) | called by muse, mutect2
- FRMPD4 | c.-18G>A | 5'UTR (SNP) | VAF 12/248 reads (5%) | called by muse, mutect2
- HBP1 | c.1527+36C>T | Intron (SNP) | VAF 8/197 reads (4%) | catalogued as rs1443737633; called by muse, mutect2
